Gene-level copy-number profile of tumor specimen ALCH-AFG5-TTP1-A from ALCHEMIST case ALCH-AFG5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.2 years (18,684 days).
Specimen ALCH-AFG5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 249a82e8-7d6c-43bf-a769-99fa137ba329.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFG5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/6fddece8-04e6-4e3f-9513-b377c87827bd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 8,326; copy number 2: 44,575; copy number 3: 5,971; copy number 4: 11; copy number 5: 1; copy number 6: 11; copy number 7: 4; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,532,166–46,570,255, 3 genes (within-gene range 0–2): TMEM275, MKNK1-AS1, KNCN.
- chr3:96,359,964–96,360,039, 1 gene: MIR8060.
- chr17:3,577,955–3,578,853, 1 gene (within-gene range 0–1): AC027796.5.
- chr17:20,647,287–20,681,799, 1 gene: AC087499.5.
- chr22:18,150,170–18,177,397, 1 gene: USP18.
- chr22:18,516,344–18,530,573, 4 genes: GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,992,422–136,993,984, 1 gene, copy number 6: PAXX.
- chr11:65,487,241–65,506,516, 6 genes, copy number 6: LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3.
- chr20:62,952,707–62,969,585, 1 gene, copy number 5: SLC17A9.
- chr22:18,178,038–18,345,899, 2 genes, copy number 7: FAM230D, GGTLC5P.
- chr22:18,533,646–18,611,919, 4 genes, copy number 6: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.
- chr22:18,636,445–18,638,405, 1 gene, copy number 17: CA15P2.
- chr22:18,906,238–18,947,732, 2 genes, copy number 7 (within-gene range 2–7): AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 6,570. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
